Somatic mutation profile of tumor specimen TCGA-04-1332-01A (aliquot TCGA-04-1332-01A-01W-0488-09) from TCGA case TCGA-04-1332, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.6 years (25,786 days).
Specimen TCGA-04-1332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b249eaa9-577f-4c64-bb52-14468feae088.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1332-10A (Blood Derived Normal), aliquot TCGA-04-1332-10A-01W-0489-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/620a93bd-bcb4-4c24-8605-48709007e9e7

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 73/141 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; called by muse, mutect2, varscan2
- AP3B2 | c.2654G>A p.R885H (on ENST00000261722; = p.R879H on NM_004644.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs758946710, COSV55608547; called by muse, mutect2, varscan2
- AP4B1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs564262237, COSV56724436; called by muse, mutect2, varscan2
- B3GNT2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs1447195244, COSV57344005; called by muse, mutect2, varscan2
- CFAP70 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs140163805; called by muse, varscan2
- DNAH11 | c.10175G>A p.R3392H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs773319818, COSV60941018, COSV60950323; called by muse, mutect2, varscan2
- DNAH17 | c.4161G>T p.Q1387H | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV67749668; called by muse, mutect2
- EPHB2 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV65866397; called by muse, mutect2, varscan2
- ERCC6 | c.1669C>G p.R557G | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63394062; called by muse, mutect2, varscan2
- HPS3 | c.1891G>T p.V631F | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV56057347; called by muse, mutect2, varscan2
- IL6R | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as rs764209461, COSV59819161; called by muse, mutect2, varscan2
- KRTAP13-1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62664629; called by muse, mutect2
- MAP3K13 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs188669013, COSV53986166, COSV53996158; called by muse, mutect2, varscan2
- NUAK1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752482605, COSV54606111; called by muse, mutect2
- OR2J3 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as rs751049860, COSV65849350; called by muse, mutect2
- PMPCB | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV50787874; called by muse, mutect2, varscan2
- PORCN | c.140T>G p.L47W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV58227122; called by muse, mutect2, varscan2
- PSTPIP2 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.787); catalogued as rs1421291932, COSV68958857; called by muse, mutect2, varscan2
- RELB | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1259719710, COSV55508351; called by muse, mutect2, varscan2
- SERPINF1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); catalogued as rs781061700, COSV54617688; called by muse, mutect2, varscan2
- SIM2 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761310285; called by mutect2, varscan2
- SULF2 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs755453376; called by muse, varscan2
- TCHH | c.4085T>A p.F1362Y | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV64277600; called by muse, mutect2
- TFE3 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs782769489, COSV59947337; called by muse, mutect2, varscan2
- TPK1 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV63647605; called by muse, mutect2, varscan2
- TTN | c.68270G>A p.R22757H (on ENST00000591111; = p.R15333H on NM_003319.4) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | PolyPhen benign (0.007); catalogued as rs757790881, COSV60310378; called by muse, mutect2, varscan2
- TTN | c.45203A>G p.K15068R (on ENST00000591111; = p.K7644R on NM_003319.4) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | PolyPhen probably damaging (0.937); catalogued as COSV60319127; called by muse, mutect2, varscan2
- ZNF415 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199811601; called by muse, mutect2
- CARS2 | c.1317G>A p.K439= | Splice Region (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CLPTM1 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTPS2 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF2AK3 | c.1869G>C p.R623S | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2
- FBXW12 | c.326T>A p.L109H | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- HDLBP | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- HECW1 | c.2121C>A p.C707* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- ITGA9 | c.1349del p.M450Sfs*40 | Frame Shift Del (DEL) | VAF 39/287 reads (14%) | called by mutect2, pindel, varscan2
- LAIR1 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.782); called by muse, mutect2
- LRRCC1 | c.2378G>T p.S793I | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- NKTR | c.4122C>A p.Y1374* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- NUP188 | c.2855G>A p.S952N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- PBX2 | c.870+1G>T p.X290_splice | Splice Site (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- RNF220 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SUPT20HL2 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- TBL1X | c.1555T>C p.Y519H | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.098); called by muse, mutect2
- TRIM28 | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF114 | c.1191del p.F397Lfs*33 | Frame Shift Del (DEL) | VAF 80/471 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.3294G>C p.S1098= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100941448; called by muse, mutect2
- CENPE | c.6570C>T p.S2190= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV54389286; called by muse, mutect2, varscan2
- GPRC6A | c.2722A>C p.R908= | Silent (SNP) | VAF 80/394 reads (20%) | catalogued as COSV59955757; called by muse, mutect2, varscan2
- LELP1 | c.279C>T p.P93= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV64202713, COSV64202725; called by muse, mutect2, varscan2
- NCL | c.1851C>T p.F617= | Silent (SNP) | VAF 54/359 reads (15%) | catalogued as rs1007436333, COSV59547432; called by muse, mutect2, varscan2
- NKTR | c.4164C>A p.S1388= | Silent (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- RANBP6 | c.999T>C p.D333= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV52391397; called by muse, mutect2, varscan2
- TAS2R41 | c.816C>T p.V272= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- ZNF569 | c.1983C>G p.P661= | Silent (SNP) | VAF 35/1016 reads (3%) | catalogued as COSV100386601, COSV57597103; called by muse, mutect2
- RPL23A | c.456+85C>A | Intron (SNP) | VAF 26/604 reads (4%) | catalogued as COSV99411681; called by muse, mutect2
